Somatic mutation profile of tumor specimen MBCProject_1509_T1_WES (aliquot MBCProject_1509_T1_WES_1) from CMI case MBCProject_1509, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.0 years (13,865 days).
Specimen MBCProject_1509_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c22bec3e-8273-4e90-9709-481059776ac5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1509_SALIVA (Saliva), aliquot MBCProject_1509_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9726f30-5cf7-4c95-8eb9-aa489d39e548

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA3 | c.878T>A p.M293K | Missense Mutation (SNP) | VAF 213/539 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161496, COSV60515607, COSV60521489; called by muse, mutect2, varscan2
- CPZ | c.883G>A p.G295S (on ENST00000360986 / NM_001014447.3; = p.G284S on NM_003652.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778557300, COSV100248848, COSV59924724; called by muse, mutect2, varscan2
- MINAR1 | c.2630T>C p.L877P | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59587159; called by muse, mutect2, varscan2
- NUMA1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs201363056, COSV61184438; called by muse, mutect2, varscan2
- ANTXR1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDI1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DST | c.7771_7772insCT p.N2591Tfs*19 | Frame Shift Ins (INS) | VAF 27/86 reads (31%) | called by mutect2, varscan2
- DST | c.7768_7769del p.S2590* | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | called by mutect2, varscan2
- FOXA1 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MYNN | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PP2D1 | c.1755C>A p.D585E | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF175 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RWDD3 | c.35_42del p.L12Hfs*28 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- SSBP1 | c.287A>C p.D96A | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- SYTL5 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- TRIO | c.6438G>A p.M2146I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2
- EPAS1 | c.2091G>A p.P697= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs769061243; called by muse, mutect2, varscan2
- JKAMP | c.624T>G p.A208= (on ENST00000554271 / NM_001284201.1; = p.A194= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- MDN1 | c.12897C>T p.I4299= | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- WDFY3 | c.8118C>T p.F2706= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
